Somatic mutation profile of tumor specimen MMRF_2014_1_BM_CD138pos (aliquot MMRF_2014_1_BM_CD138pos_T1_KHS5U_L08069) from MMRF case MMRF_2014, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.7 years (22,537 days).
Specimen MMRF_2014_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4695f5f4-ac1e-46b2-a185-1440cc1eb620.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2014_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2014_1_PB_Whole_C2_KHS5U_L08070; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f12d6a00-1424-4517-a91e-1a10294e5164

The open-access MAF lists 131 somatic variants for this specimen: 53 protein-altering or splice-affecting, 16 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, 3'UTR 31, Intron 16, Silent 16, 5'UTR 10, 5'Flank 3, Nonsense Mutation 2, Splice Site 2, 3'Flank 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- A1CF | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs769423582; called by muse, mutect2, varscan2
- ANK2 | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 146/228 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs200124480, COSV99999845; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C19orf84 | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV55740121; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 116/246 reads (47%) | catalogued as rs782442161; called by mutect2, pindel, varscan2
- FGF23 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); catalogued as rs1223908863, COSV52974961, COSV52975341; called by muse, mutect2, varscan2
- H2BC14 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs760473010, COSV60797732; called by muse, mutect2, varscan2
- HNRNPDL | c.479G>C p.S160T | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.193); catalogued as rs1234147938; called by muse, mutect2
- HRNR | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 175/367 reads (48%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.468); catalogued as COSV100914103; called by muse, mutect2, varscan2
- IGHV2-70 | c.158T>A p.M53K | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs1555607329; called by muse, varscan2
- IGHV2-70 | c.54A>C p.L18F | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs187704106; called by muse, mutect2, varscan2
- IGLV3-21 | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs189479110; called by muse, varscan2
- INTS9 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs141006653; called by muse, mutect2, varscan2
- KALRN | c.4192C>A p.Q1398K | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs770113483; called by muse, mutect2, varscan2
- NBEA | c.6556G>A p.D2186N | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV59768340, COSV59815022; called by muse, mutect2, varscan2
- RNF148 | c.520A>T p.T174S | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100411667; called by muse, mutect2, varscan2
- SP3 | c.2096A>G p.H699R | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59469881; called by muse, mutect2, varscan2
- TDRD5 | c.1157C>G p.A386G | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs199682173; called by muse, mutect2, varscan2
- TTN | c.26808G>A p.M8936I (on ENST00000591111; = p.M8009I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | PolyPhen benign (0.011); catalogued as rs1477695783; called by muse, mutect2, varscan2
- VANGL1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV59619127, COSV59622424; called by muse, mutect2, varscan2
- AADACL3 | c.1094T>G p.V365G | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ABCC6 | c.1870G>C p.A624P | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C4orf54 | c.4759C>T p.P1587S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CDHR3 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 6/160 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.102); called by muse, mutect2
- DIS3 | c.2794-1G>C p.X932_splice | Splice Site (SNP) | VAF 19/27 reads (70%) | called by muse, mutect2, varscan2
- DUSP2 | c.746G>T p.S249I | Missense Mutation (SNP) | VAF 112/234 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- GUCY2F | c.3256C>G p.L1086V | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- HECTD4 | c.9581G>C p.G3194A | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- HUWE1 | c.2189A>C p.E730A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- IGLV4-69 | c.115A>C p.K39Q | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); called by muse, varscan2
- INTS4 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA2 | c.574A>T p.K192* | Nonsense Mutation (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- LATS2 | c.2211C>A p.D737E | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGEL2 | c.896C>G p.T299S | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- MKLN1 | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MUC3A | c.8453C>T p.S2818F | Missense Mutation (SNP) | VAF 15/345 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); called by muse, mutect2
- MYCN | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NTN5 | c.1466A>T p.H489L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- OR5T3 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 131/293 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PCDHA5 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PCDHGA9 | c.864A>C p.Q288H | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PNO1 | c.227G>T p.R76M | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PREX2 | c.2517G>A p.M839I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRMT5 | c.983A>G p.E328G | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RFWD3 | c.870T>A p.C290* | Nonsense Mutation (SNP) | VAF 44/113 reads (39%) | called by muse, mutect2, varscan2
- SMPD4 | c.489G>C p.E163D | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- SPINDOC | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TPRG1L | c.529A>G p.N177D | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TRIP11 | c.1889C>A p.S630Y | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- UGT2B15 | c.1567A>C p.K523Q | Missense Mutation (SNP) | VAF 109/375 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- WIZ | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YEATS2 | c.3761T>A p.L1254Q | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZFR | c.55dup p.E19Gfs*28 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | called by pindel, varscan2
- ABLIM1 | c.75G>A p.E25= | Silent (SNP) | VAF 97/187 reads (52%) | catalogued as rs746889426; called by muse, mutect2, varscan2
- ADRA2A | c.618C>T p.N206= | Silent (SNP) | VAF 135/265 reads (51%) | called by muse, mutect2, varscan2
- COG5 | c.69T>A p.A23= | Silent (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- DGAT2 | c.480C>T p.Y160= | Silent (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- FBN3 | c.2805G>C p.R935= | Silent (SNP) | VAF 27/206 reads (13%) | catalogued as COSV54461619; called by muse, mutect2, varscan2
- HMCN2 | c.1683C>T p.G561= | Silent (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- IGLV3-21 | c.258G>A p.G86= | Silent (SNP) | VAF 26/30 reads (87%) | catalogued as rs745828571; called by muse, varscan2
- IGLV4-60 | c.261C>T p.F87= | Silent (SNP) | VAF 76/84 reads (90%) | called by muse, mutect2, varscan2
- IGLV4-69 | c.57C>T p.L19= | Silent (SNP) | VAF 106/236 reads (45%) | called by muse, varscan2
- IGLV4-69 | c.231C>T p.S77= | Silent (SNP) | VAF 52/99 reads (53%) | catalogued as rs768196983; called by muse, mutect2, varscan2
- SP140 | c.912T>G p.T304= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV59446444; called by muse, mutect2, varscan2
- SV2C | c.2028G>A p.A676= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs183714782, COSV59226703, COSV59230097; called by muse, varscan2
- TENM3 | c.7959C>A p.G2653= | Silent (SNP) | VAF 52/84 reads (62%) | catalogued as rs760455233; called by muse, mutect2, varscan2
- TMEM26 | c.1086C>T p.D362= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs545126171; called by muse, mutect2, varscan2
- TNFRSF1A | c.1338C>A p.A446= | Silent (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- ZNF540 | c.1614T>A p.L538= | Silent (SNP) | VAF 81/158 reads (51%) | called by muse, mutect2, varscan2
- AATK | c.-8G>T | 5'UTR (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- ABCG4 | c.*188G>T | 3'UTR (SNP) | VAF 82/389 reads (21%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.2006+1574T>C | Intron (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- ADD3 | c.*1116A>C | 3'UTR (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- AGPAT4 | c.843+2455C>A | Intron (SNP) | VAF 153/363 reads (42%) | called by muse, mutect2, varscan2
- AP4E1 | chr15:50908678 C>T | 5'Flank (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- AVPR1B | c.-343G>T | 5'UTR (SNP) | VAF 58/129 reads (45%) | called by muse, mutect2, varscan2
- CACNA1E | c.*537A>G | 3'UTR (SNP) | VAF 31/75 reads (41%) | called by muse, mutect2, varscan2
- CCNYL1 | c.*10T>C | 3'UTR (SNP) | VAF 92/208 reads (44%) | called by muse, mutect2, varscan2
- CCR2 | c.*83T>A | 3'UTR (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2, varscan2
- CD84 | chr1:160545635 A>T | 3'Flank (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2
- CEP350 | c.*790C>T | 3'UTR (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2, varscan2
- CGB7 | c.-1098G>T | 5'UTR (SNP) | VAF 12/31 reads (39%) | catalogued as COSV56825230; called by muse, mutect2, varscan2
- DNAH14 | c.3537+2520G>A | Intron (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- DNAJC17 | c.*1672C>T | 3'UTR (SNP) | VAF 67/109 reads (61%) | catalogued as rs992879304; called by muse, mutect2, varscan2
- DSEL | c.-515dup | 5'UTR (INS) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- EFNA5 | c.*710A>G | 3'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- ENPEP | c.*3692T>C | 3'UTR (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- ERP44 | c.*1829G>C | 3'UTR (SNP) | VAF 57/92 reads (62%) | called by muse, mutect2, varscan2
- FOXM1 | c.*408G>C | 3'UTR (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- G6PC2 | c.*91A>G | 3'UTR (SNP) | VAF 68/221 reads (31%) | called by muse, mutect2, varscan2
- GCLC | c.759+447A>G | Intron (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- HEPH | c.*347A>T | 3'UTR (SNP) | VAF 17/18 reads (94%) | called by muse, mutect2, varscan2
- INF2 | c.*292G>A | 3'UTR (SNP) | VAF 17/57 reads (30%) | catalogued as rs551404122; called by muse, mutect2, varscan2
- IQCE | c.*614C>T | 3'UTR (SNP) | VAF 101/209 reads (48%) | called by muse, mutect2, varscan2
- KLK2 | c.46+33G>T | Intron (SNP) | VAF 30/87 reads (34%) | catalogued as rs751998602; called by muse, mutect2, varscan2
- LAPTM4B | c.-624A>T | 5'UTR (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- LPP | c.1240+1458C>T | Intron (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- LRRC37A5P | n.251-4014A>T | Intron (SNP) | VAF 77/130 reads (59%) | catalogued as rs1445161313; called by muse, mutect2, varscan2
- LTB | c.162+24G>T | Intron (SNP) | VAF 41/97 reads (42%) | catalogued as COSV53000576; called by muse, mutect2, varscan2
- LTB | c.162+23G>T | Intron (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- MAMDC2 | c.*480T>C | 3'UTR (SNP) | VAF 86/137 reads (63%) | called by muse, mutect2, varscan2
- MTHFSD | chr16:86555448 C>A | 5'Flank (SNP) | VAF 78/188 reads (41%) | called by muse, mutect2, varscan2
- NAGA | c.-388G>C | 5'UTR (SNP) | VAF 40/166 reads (24%) | catalogued as rs1034496439; called by muse, mutect2
- NAGA | c.-390C>T | 5'UTR (SNP) | VAF 41/166 reads (25%) | called by muse, mutect2
- NCAM2 | c.*3177T>C | 3'UTR (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- NCR3LG1 | c.*2301G>T | 3'UTR (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- NDUFA5 | c.66+133C>A | Intron (SNP) | VAF 69/212 reads (33%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.1565T>G | RNA (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- NHLH2 | chr1:115842506 G>C | 5'Flank (SNP) | VAF 51/99 reads (52%) | called by muse, mutect2, varscan2
- NR6A1 | c.*4762C>T | 3'UTR (SNP) | VAF 5/94 reads (5%) | catalogued as rs892542395; called by muse, mutect2
- OR2AJ1 | c.*68G>C | 3'UTR (SNP) | VAF 70/124 reads (56%) | called by muse, mutect2, varscan2
- OR4Q3 | c.*134A>G | 3'UTR (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2, varscan2
- PHOX2B | c.*11T>C | 3'UTR (SNP) | VAF 18/86 reads (21%) | called by muse, varscan2
- POP1 | c.*93C>A | 3'UTR (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- POU5F1B | c.-158C>A | 5'UTR (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- RGS4 | c.*1131C>T | 3'UTR (SNP) | VAF 15/38 reads (39%) | catalogued as rs1400941518; called by muse, mutect2, varscan2
- ROBO1 | c.918-59T>A | Intron (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2
- RPS18 | c.384-58T>C | Intron (SNP) | VAF 113/244 reads (46%) | called by muse, mutect2, varscan2
- SC5D | c.*167C>T | 3'UTR (SNP) | VAF 23/171 reads (13%) | called by muse, mutect2, varscan2
- SLITRK6 | c.*685T>G | 3'UTR (SNP) | VAF 30/31 reads (97%) | called by muse, mutect2, varscan2
- SORT1 | c.*3016C>T | 3'UTR (SNP) | VAF 27/62 reads (44%) | catalogued as rs906849121; called by muse, mutect2, varscan2
- TDG | c.24-3948C>T | Intron (SNP) | VAF 19/218 reads (9%) | called by muse, mutect2
- TEF | c.-127C>T | 5'UTR (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- TLN2 | c.-36-9364T>G | Intron (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- TMSB4X | c.-17+81G>C | Intron (SNP) | VAF 85/86 reads (99%) | called by muse, mutect2, varscan2
- TRAPPC6B | c.-173T>C | 5'UTR (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2, varscan2
- TTPA | c.*515C>T | 3'UTR (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- TTYH3 | c.*1635del | 3'UTR (DEL) | VAF 34/265 reads (13%) | called by mutect2, pindel, varscan2
- WSB2 | c.*217_*245del | 3'UTR (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel
- XBP1 | c.227+236C>G | Intron (SNP) | VAF 40/94 reads (43%) | catalogued as COSV99321462; called by muse, varscan2
- ZDHHC3 | c.*352G>C | 3'UTR (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
